Somatic mutation profile of tumor specimen 0DN1DE from CCDI case PBCABJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.7 years (7,212 days).
Specimen 0DN1DE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab926dbd-1c4c-4654-8d9e-cc9e4a057eb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN1AY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18d64ff2-619d-4a4d-ac91-185d6b17e0ac

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Nonsense Mutation 2, Intron 1, In Frame Del 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANCA | c.3482C>T p.T1161M | Missense Mutation (SNP) | VAF 92/326 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs142833057; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 92/296 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 158/261 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC126283.2 | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 266/800 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs1210626952, CM104003; called by muse, mutect2, varscan2
- ATRX | c.5215C>T p.R1739* | Nonsense Mutation (SNP) | VAF 279/437 reads (64%) | catalogued as COSV64873412; called by muse, mutect2, varscan2
- ATRX | c.2431C>T p.Q811* | Nonsense Mutation (SNP) | VAF 28/608 reads (5%) | catalogued as COSV64876298; called by muse, mutect2
- CYB5RL | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.44); catalogued as rs369139472; called by muse, mutect2, varscan2
- FGF16 | c.378G>A p.S126= | Splice Region (SNP) | VAF 12/158 reads (8%) | catalogued as rs781972271, CS149597; called by muse, mutect2
- LRFN5 | c.860C>G p.P287R | Missense Mutation (SNP) | VAF 97/281 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53242610; called by muse, mutect2, varscan2
- MET | c.1982G>A p.S661N | Missense Mutation (SNP) | VAF 207/604 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs755139610; called by muse, mutect2, varscan2
- MICAL2 | c.5184_5198del p.P1729_T1733del | In Frame Del (DEL) | VAF 8/170 reads (5%) | catalogued as rs781337177; called by mutect2, varscan2*
- CPNE3 | c.1037G>A p.G346D | Missense Mutation (SNP) | VAF 151/618 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SGPL1 | c.101G>T p.C34F | Missense Mutation (SNP) | VAF 160/703 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF469 | c.11107A>G p.S3703G (on ENST00000437464; = p.S3731G on NM_001367624.2) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- BCORL1 | c.3345G>T p.P1115= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as COSV54401490, COSV99500865; called by muse, mutect2, varscan2
- CYP2A13 | c.936C>T p.Y312= | Silent (SNP) | VAF 117/417 reads (28%) | catalogued as rs551460816, COSV57839165; called by muse, mutect2, varscan2
- DNAH14 | c.7486-5735G>A | Intron (SNP) | VAF 52/870 reads (6%) | catalogued as rs796325602; called by muse, mutect2
- POTEC | chr18:14511891 G>C | 3'Flank (SNP) | VAF 174/644 reads (27%) | called by muse, mutect2, varscan2
